Somatic mutation profile of tumor specimen TCGA-EE-A17Z-06A (aliquot TCGA-EE-A17Z-06A-11D-A196-08) from TCGA case TCGA-EE-A17Z, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; Age at diagnosis: 57.6 years (21,041 days).
Specimen TCGA-EE-A17Z-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 94512f8b-5f1c-48ad-96e8-d63cdbf2001b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-EE-A17Z-10A (Blood Derived Normal), aliquot TCGA-EE-A17Z-10A-01D-A198-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e0342903-81c4-4993-bca4-8471b53ccae5

The open-access MAF lists 23 somatic variants for this specimen: 19 protein-altering or splice-affecting, 4 silent.
By variant classification: Missense Mutation 17, Silent 4, Nonsense Mutation 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PTEN | c.752G>T p.G251V | Missense Mutation (SNP) | VAF 19/20 reads (95%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as rs1554825226, COSV64289114, COSV64289498, COSV64301765; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CCDC160 | c.256A>G p.I86V | Missense Mutation (SNP) | VAF 7/8 reads (88%) | SIFT tolerated (0.1); PolyPhen benign (0.072); catalogued as COSV66251633; called by muse, mutect2, varscan2
- CLCA2 | c.515G>T p.G172V | Missense Mutation (SNP) | VAF 52/113 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1387083715, COSV65287161; called by mutect2, varscan2
- DHX38 | c.199G>A p.D67N | Missense Mutation (SNP) | VAF 16/18 reads (89%) | SIFT tolerated (0.3); PolyPhen benign (0.001); catalogued as rs184511349; called by mutect2, varscan2
- DNAH9 | c.2321C>T p.A774V | Missense Mutation (SNP) | VAF 12/46 reads (26%) | SIFT tolerated (0.29); PolyPhen benign (0.007); catalogued as COSV52349612; called by mutect2, varscan2
- DPYSL5 | c.872C>T p.A291V | Missense Mutation (SNP) | VAF 58/131 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs554329592, COSV56510790; called by muse, mutect2, varscan2
- FCGR2C | c.805C>G p.R269G | Missense Mutation (SNP) | VAF 7/27 reads (26%) | SIFT tolerated (0.08); PolyPhen benign (0.121); catalogued as COSV63437346; called by muse, mutect2, varscan2
- IGF1R | c.1094G>C p.R365P | Missense Mutation (SNP) | VAF 17/53 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV51271054, COSV51279483, COSV51287490; called by muse, mutect2, varscan2
- KMT2C | c.4613T>A p.L1538* | Nonsense Mutation (SNP) | VAF 25/25 reads (100%) | catalogued as COSV51439489, COSV51490763; called by muse, mutect2, varscan2
- MAP3K6 | c.1319A>T p.D440V | Missense Mutation (SNP) | VAF 13/21 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1440407766, COSV62888475; called by muse, mutect2, varscan2
- NCOA3 | c.1078C>G p.R360G | Missense Mutation (SNP) | VAF 37/93 reads (40%) | SIFT deleterious (0.05); PolyPhen benign (0.201); catalogued as COSV59068577; called by muse, mutect2, varscan2
- SCAP | c.1297A>G p.M433V | Missense Mutation (SNP) | VAF 54/92 reads (59%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.841); catalogued as COSV55561317; called by muse, mutect2, varscan2
- SNW1 | c.1199G>T p.R400L | Missense Mutation (SNP) | VAF 38/96 reads (40%) | SIFT tolerated (0.31); PolyPhen benign (0.17); catalogued as COSV53174157; called by muse, mutect2, varscan2
- SOHLH1 | c.335A>T p.E112V | Missense Mutation (SNP) | VAF 31/68 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.829); catalogued as COSV53681613; called by muse, mutect2, varscan2
- ST6GALNAC3 | c.409C>G p.L137V | Missense Mutation (SNP) | VAF 18/35 reads (51%) | PolyPhen possibly damaging (0.646); catalogued as COSV60332217, COSV60338945; called by muse, mutect2, varscan2
- TRIM38 | c.1201A>G p.T401A | Missense Mutation (SNP) | VAF 26/90 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.007); catalogued as rs754349053, COSV62642165; called by muse, mutect2, varscan2
- ZFX | c.2312C>G p.T771R | Missense Mutation (SNP) | VAF 37/43 reads (86%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58447599; called by muse, mutect2, varscan2
- ASF1B | c.322del p.R108Efs*21 | Frame Shift Del (DEL) | VAF 19/56 reads (34%) | called by mutect2, pindel, varscan2
- CTNNA2 | c.628C>G p.R210G | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- C1QTNF4 | c.702G>T p.T234= | Silent (SNP) | VAF 4/14 reads (29%) | catalogued as rs1190202193; called by mutect2, varscan2
- FMNL1 | c.297G>A p.K99= | Silent (SNP) | VAF 12/31 reads (39%) | catalogued as COSV58956929; called by muse, mutect2, varscan2
- MED22 | c.396G>A p.E132= | Silent (SNP) | VAF 26/56 reads (46%) | catalogued as COSV59298295; called by muse, varscan2
- PCNX1 | c.4932T>C p.P1644= | Silent (SNP) | VAF 27/72 reads (38%) | catalogued as COSV53094759; called by muse, mutect2, varscan2
